Somatic mutation profile of tumor specimen TCGA-CH-5740-01A (aliquot TCGA-CH-5740-01A-11D-1576-08) from TCGA case TCGA-CH-5740, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.2 years (20,880 days).
Specimen TCGA-CH-5740-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80db0b4-e22f-4785-b862-fe959629dd6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5740-10A (Blood Derived Normal), aliquot TCGA-CH-5740-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdfef2d3-135b-451b-9a6d-74cc421778ce

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Del 2, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV54389462; called by muse, mutect2
- AIM2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 107/488 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV63699325; called by muse, mutect2, varscan2
- BICRA | c.3373C>T p.P1125S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV67604436; called by muse, mutect2
- CD46 | c.397T>G p.L133V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV59732616; called by muse, mutect2, varscan2
- CR1L | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54324997; called by muse, mutect2, varscan2
- CYTL1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs749759953, COSV57036649; called by muse, mutect2, varscan2
- ERICH3 | c.2510G>T p.R837M | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV58602882, COSV58613584; called by muse, mutect2
- KIF3B | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 65/200 reads (33%) | catalogued as rs149015672; called by muse, mutect2, varscan2
- LCE2D | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV64228940; called by muse, mutect2, varscan2
- MEPCE | c.746A>C p.H249P | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV52769030; called by muse, mutect2
- MUC17 | c.6620G>A p.G2207D | Missense Mutation (SNP) | VAF 95/476 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs201412788; called by muse, mutect2, varscan2
- MYO6 | c.3167+1G>A p.X1056_splice (on ENST00000369981; = p.X1046_splice on NM_004999.4) | Splice Site (SNP) | VAF 46/147 reads (31%) | catalogued as rs200713129; called by muse, mutect2, varscan2
- OR11L1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV63314113; called by muse, mutect2, varscan2
- OVGP1 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63858176; called by muse, mutect2
- SMPDL3A | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV63755286; called by muse, mutect2, varscan2
- TMPRSS2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs139092674; called by muse, mutect2, varscan2
- CEP57L1 | c.613_616del p.E205Kfs*25 | Frame Shift Del (DEL) | VAF 33/150 reads (22%) | called by mutect2, pindel, varscan2
- MECOM | c.2630del p.K877Rfs*4 (on ENST00000468789 / NM_001105078.4; = p.K1065Rfs*4 on NM_004991.4) | Frame Shift Del (DEL) | VAF 32/303 reads (11%) | called by mutect2, pindel, varscan2
- PCSK6 | c.966T>G p.A322= | Silent (SNP) | VAF 8/262 reads (3%) | catalogued as COSV59340071; called by muse, mutect2
- POLDIP2 | c.558C>T p.S186= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV50228318; called by muse, varscan2
- XKR7 | c.939C>T p.R313= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs754406842, COSV73813134; called by muse, mutect2, varscan2
- NTNG1 | c.1087+10900G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs762718931, COSV64270039; called by muse, mutect2, varscan2
